Gene-level copy-number profile of tumor specimen HTMCP-03-06-02047-01A from CGCI case HTMCP-03-06-02047, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 47.4 years (17,304 days).
Specimen HTMCP-03-06-02047-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e7312dd4-abd9-4081-9744-1e304b2fb7e4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02047-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/bf218726-a927-4aca-84dd-3f070d6cf0ea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 2,040; copy number 2: 32,355; copy number 3: 19,927; copy number 4: 3,020; copy number 5: 71; copy number 6: 935.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr5:165,609,441–165,905,608, 3 genes (within-gene range 0–1): RN7SKP60, AC008562.1, AC008489.1.
- chr9:39,631,046–39,874,562, 8 genes: FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, BX664615.2.
- chr9:41,890,314–42,499,134, 14 genes: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:64,369,394–64,765,535, 14 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 938 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:142,724,034–144,187,020, 24 genes, copy number 6: TRPC1, RNU7-47P, PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1, PBX2P1, SLC9A9, AC131210.1, SLC9A9-AS1, SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144.
- chr3:145,523,538–198,123,232, 913 genes, copy number 5–6 (broad region; genes not listed).
- chr12:71,125,085–71,441,898, 1 gene, copy number 5 (within-gene range 4–5): TSPAN8.

Autosomal genes at a single copy (total copy number 1): 1,214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
